Somatic mutation profile of tumor specimen MP2PRT-PAWBHS-TMP1-A (aliquot MP2PRT-PAWBHS-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAWBHS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,003 days).
Specimen MP2PRT-PAWBHS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35272503-7263-42b7-9959-37c375b9b54b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWBHS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWBHS-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36c5e181-002a-4e3f-ab69-16c0c359542b

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 192/580 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- RNF180 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 146/440 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267600665; called by muse, mutect2, varscan2
- WWC1 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 158/383 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs1008923842; called by muse, mutect2, varscan2
- ASPM | c.4250_4251del p.Y1417* | Frame Shift Del (DEL) | VAF 118/372 reads (32%) | called by pindel, varscan2
- SPTBN5 | c.7552G>T p.E2518* | Nonsense Mutation (SNP) | VAF 141/341 reads (41%) | called by muse, mutect2, varscan2
- DSP | c.6897C>G p.G2299= | Silent (SNP) | VAF 94/416 reads (23%) | catalogued as rs1459176618; called by muse, mutect2, varscan2
- HS3ST6 | c.567C>T p.S189= | Silent (SNP) | VAF 311/922 reads (34%) | catalogued as rs764098722, COSV53536447; called by muse, mutect2, varscan2
- LILRA2 | c.1260A>C p.A420= | Silent (SNP) | VAF 216/652 reads (33%) | called by muse, mutect2, varscan2
- MAN2C1 | c.2859C>T p.P953= | Silent (SNP) | VAF 46/794 reads (6%) | catalogued as rs78992660; called by muse, mutect2
